Somatic mutation profile of tumor specimen TARGET-10-PATGLV-09A (aliquot TARGET-10-PATGLV-09A-01D) from TARGET case TARGET-10-PATGLV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,257 days).
Specimen TARGET-10-PATGLV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02677e7d-5da6-47d1-be5d-bc3990afeb07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGLV-10A (Blood Derived Normal), aliquot TARGET-10-PATGLV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b94ee2-4320-4acc-9a16-8c43eff48d3c

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS2 | c.2904T>G p.S968R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.112); catalogued as COSV57392403; called by muse, mutect2
- DIP2C | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1427448887, COSV99794381; called by muse, mutect2
- KRT16 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs143438105; called by muse, mutect2, varscan2
- KRTAP13-1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374257240, COSV62664445; called by muse, mutect2, varscan2
- PC | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs779355042; called by muse, mutect2, varscan2
- PHF6 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 21/23 reads (91%) | catalogued as COSV59700130; called by muse, mutect2, varscan2
- PRKD3 | c.1199T>A p.L400Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52220915; called by muse, mutect2, varscan2
- SSTR3 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60730704; called by muse, mutect2, varscan2
- TLL1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376169735; called by muse, mutect2, varscan2
- TNNC1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51768789; called by muse, mutect2, varscan2
- NOTCH1 | c.7330_7352delinsGGGG p.Q2444Gfs*27 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by pindel, varscan2*
- ARFGEF3 | c.5406C>T p.G1802= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs756704668, COSV52462095, COSV99294608, COSV99294802; called by muse, mutect2, varscan2
- CCKBR | c.1146G>A p.S382= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- P3H1 | c.1125G>A p.L375= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs1272006953; called by muse, mutect2, varscan2
- TAS2R39 | c.81T>C p.S27= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- CLDN18 | c.-6G>A | 5'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs780283140, COSV59302692; called by muse, mutect2, varscan2
